Somatic mutation profile of tumor specimen ALCH-B2NE-TTP1-A (aliquot ALCH-B2NE-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2NE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 60.3 years (22,007 days).
Specimen ALCH-B2NE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f2ab090-c7e2-4858-87cd-f9db416f46ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2NE-NB1-A (Blood Derived Normal), aliquot ALCH-B2NE-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f18fb556-2035-4eb9-a61d-f4252ed0f67e

The open-access MAF lists 500 somatic variants for this specimen: 341 protein-altering or splice-affecting, 95 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 95, Intron 28, Nonsense Mutation 24, Splice Site 13, Frame Shift Del 12, 3'UTR 11, RNA 10, Frame Shift Ins 6, 5'Flank 6, 5'UTR 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763169384; called by muse, mutect2, varscan2
- ACTN3 | c.344C>A p.A115D | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as rs757226651; called by muse, mutect2, varscan2
- ADCYAP1 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs1239775064, COSV52486170; called by muse, mutect2, varscan2
- AFDN | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745327506, COSV60036416; called by muse, mutect2, varscan2
- AMPH | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57739538; called by muse, mutect2, varscan2
- AMY2A | c.238G>T p.V80F | Missense Mutation (SNP) | VAF 116/355 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV101340680; called by muse, mutect2, varscan2
- APEH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs748036222; called by muse, mutect2, varscan2
- ARID1A | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV61372408, COSV61376450, COSV61388912; called by muse, mutect2, varscan2
- ARNT2 | c.562C>A p.H188N | Missense Mutation (SNP) | VAF 54/474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763635539; called by muse, mutect2, varscan2
- ATP1A2 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 114/268 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63405744; called by muse, mutect2, varscan2
- BAG3 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64842338; called by muse, mutect2, varscan2
- BMX | c.1966C>A p.R656S | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53028315; called by muse, mutect2, varscan2
- BPIFB2 | c.766A>T p.T256S | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as rs750940543, COSV50071622; called by muse, mutect2, varscan2
- C3orf80 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.527); catalogued as rs1232972607; called by muse, mutect2, varscan2
- CABP5 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs766598543, COSV53152854; called by muse, mutect2, varscan2
- CACNA1E | c.3731G>C p.G1244A | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62408034; called by muse, mutect2, varscan2
- CAMSAP1 | c.2736G>T p.K912N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100409771; called by muse, mutect2, varscan2
- CBX2 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV53969077; called by muse, mutect2, varscan2
- CCDC86 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs760004217; called by muse, mutect2, varscan2
- CDH8 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100184625; called by muse, mutect2, varscan2
- CNBD1 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV72976331, COSV72976564; called by muse, mutect2, varscan2
- CNTNAP2 | c.3076G>T p.A1026S | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100669022; called by muse, mutect2, varscan2
- COL15A1 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757069097, COSV66646907; called by muse, mutect2, varscan2
- CRB1 | c.3879-1G>T p.X1293_splice | Splice Site (SNP) | VAF 133/623 reads (21%) | catalogued as COSV66332221; called by muse, mutect2, varscan2
- DCBLD2 | c.1187G>A p.R396K | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.13); catalogued as COSV100471550; called by muse, mutect2, varscan2
- DHX58 | c.1652A>T p.H551L | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99288616; called by muse, mutect2, varscan2
- DLX6 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs764078276; called by muse, varscan2
- DNAH5 | c.8074G>C p.G2692R | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54213683; called by muse, mutect2
- DNAH9 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV52379605; called by muse, mutect2, varscan2
- DOHH | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs753878207, COSV99170987; called by muse, mutect2, varscan2
- DYNC2H1 | c.11314del p.R3772Afs*8 | Frame Shift Del (DEL) | VAF 66/217 reads (30%) | catalogued as CM1515015; called by mutect2, pindel, varscan2
- EPHA7 | c.2459G>A p.W820* | Nonsense Mutation (SNP) | VAF 52/250 reads (21%) | catalogued as COSV65177283; called by muse, mutect2, varscan2
- ERBIN | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as rs1446681821; called by muse, mutect2, varscan2
- F13A1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs139636536, COSV53566566; called by muse, mutect2, varscan2
- FAT2 | c.9194-1G>T p.X3065_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99942086; called by muse, mutect2, varscan2
- FAT3 | c.3170G>T p.R1057L | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs778207778, COSV53083845; called by muse, mutect2, varscan2
- HAS2 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV58261923; called by muse, mutect2, varscan2
- HDGFL1 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100014550, COSV100014781; called by muse, varscan2
- HEATR5B | c.1627C>A p.Q543K | Missense Mutation (SNP) | VAF 121/302 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751294066; called by muse, mutect2, varscan2
- HECW2 | c.4351G>T p.A1451S | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs755743711; called by muse, mutect2, varscan2
- HOXD3 | c.372del p.T125Pfs*40 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as COSV50882019; called by mutect2, pindel, varscan2
- HTR1E | c.801dup p.F268Lfs*4 | Frame Shift Ins (INS) | VAF 50/218 reads (23%) | catalogued as rs753568078; called by mutect2, varscan2
- HTR6 | c.1030C>G p.R344G | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV53873156; called by muse, mutect2, varscan2
- IARS2 | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767031457; called by muse, mutect2, varscan2
- IFIT5 | c.1047del p.E350Kfs*21 | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | catalogued as COSV65655597; called by mutect2, pindel*, varscan2
- IGKV1-16 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 68/776 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs569119503; called by muse, mutect2
- IGKV1D-43 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 137/384 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs764498431; called by muse, mutect2, varscan2
- IKZF1 | c.1300G>C p.A434P | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV58791686; called by muse, mutect2, varscan2
- IL15 | c.239A>T p.H80L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs1235043296; called by muse, mutect2, varscan2
- IQUB | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100227321; called by muse, mutect2, varscan2
- ITPR1 | c.4216A>G p.I1406V (on ENST00000354582; = p.I1391V on NM_002222.7) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as rs762136714; called by muse, mutect2
- ITPRID1 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.341); catalogued as COSV60077889; called by muse, mutect2
- KCNV1 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.227); catalogued as COSV99819492; called by muse, mutect2, varscan2
- KHDC1 | c.233C>G p.T78R (on ENST00000370384 / NM_001251874.2; = p.T5R on NM_030568.5) | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV100001740; called by muse, mutect2, varscan2
- KIF2B | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs1186585823, COSV52135263; called by muse, varscan2
- KLHL1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1204276424, COSV64788621; called by muse, mutect2, varscan2
- KMT2D | c.15407A>G p.H5136R | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56488110; called by muse, mutect2
- KRTAP26-1 | c.371C>A p.P124Q | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99053416; called by muse, mutect2, varscan2
- LCE3D | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.614); catalogued as rs775921101, COSV64230771; called by muse, mutect2, varscan2
- LILRB1 | c.1688C>G p.T563R (on ENST00000427581; = p.T513R on NM_006669.6) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV61116503; called by muse, mutect2, varscan2
- LOXHD1 | c.5911G>A p.D1971N (on ENST00000642948; = p.D1909N on NM_144612.7) | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs727504544, COSV56060461; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.5147A>C p.N1716T | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV67182854; called by muse, mutect2, varscan2
- MFGE8 | c.816G>T p.Q272H | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99183986; called by muse, mutect2, varscan2
- NCAM2 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as COSV53096280; called by muse, mutect2, varscan2
- NLRP3 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 41/302 reads (14%) | catalogued as COSV60225054; called by muse, mutect2, varscan2
- NYAP2 | c.804C>G p.Y268* | Nonsense Mutation (SNP) | VAF 44/134 reads (33%) | catalogued as COSV55997949; called by muse, mutect2, varscan2
- OR1J4 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV61590122; called by muse, mutect2, varscan2
- OR2M7 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 37/266 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.029); catalogued as COSV100522751; called by mutect2, varscan2
- OR2T33 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs749258969, COSV100531472; called by muse, mutect2, varscan2
- OR2W3 | c.75G>T p.R25S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV64456091; called by muse, mutect2, varscan2
- OR4C11 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56352436, COSV56352683; called by muse, mutect2, varscan2
- OR4C6 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV100051310, COSV58606500; called by muse, mutect2, varscan2
- OR5M3 | c.557C>A p.A186D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56566374; called by muse, mutect2, varscan2
- PAQR9 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.764); catalogued as COSV61417597; called by muse, mutect2, varscan2
- PCDH15 | c.4474G>C p.A1492P | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57318116; called by muse, mutect2, varscan2
- PDGFRA | c.2917G>T p.D973Y | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99958136; called by muse, mutect2, varscan2
- PIBF1 | c.1242G>C p.R414S | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58329194; called by muse, mutect2, varscan2
- PKHD1 | c.9403G>A p.E3135K | Missense Mutation (SNP) | VAF 60/451 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV61873802; called by muse, mutect2, varscan2
- PPFIBP2 | c.891C>T p.D297= | Splice Region (SNP) | VAF 62/176 reads (35%) | catalogued as rs1459082242, COSV55083004; called by muse, mutect2, varscan2
- PRDM2 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201173386; called by muse, mutect2, varscan2
- PSME4 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1396873974, COSV99062803; called by muse, mutect2, varscan2
- PTPDC1 | c.1450G>A p.A484T (on ENST00000375360 / NM_177995.3; = p.A536T on NM_152422.4) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs763209222; called by muse, mutect2, varscan2
- PXDNL | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1293373999, COSV100681736; called by muse, mutect2, varscan2
- RFESD | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs1241949844; called by muse, mutect2, varscan2
- RHBDD3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1247895342; called by muse, mutect2, varscan2
- RPL10L | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100022388; called by muse, mutect2, varscan2
- RPLP0 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57216346; called by muse, mutect2, varscan2
- SCN1A | c.3958G>C p.A1320P (on ENST00000303395 / NM_001202435.3; = p.A1309P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD096212; called by muse, mutect2, varscan2
- SCN3A | c.2438C>G p.A813G | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV51826240; called by muse, mutect2
- SERPINB10 | c.476A>T p.E159V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99449678; called by muse, mutect2, varscan2
- SIPA1L3 | c.2978A>G p.Y993C | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749772607; called by muse, mutect2, varscan2
- SLC9A4 | c.1388C>A p.T463N | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1319840440, COSV54835471; called by muse, mutect2, varscan2
- SLC9B1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 47/1600 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56469700, COSV56471701; called by muse, mutect2
- SPATS2 | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV58918125; called by muse, mutect2, varscan2
- SPG7 | c.2240C>T p.P747L (on ENST00000268704; = p.P754L on NM_003119.4) | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs758721226; called by muse, mutect2
- STARD13 | c.800G>A p.R267Q (on ENST00000336934 / NM_001243476.3; = p.R149Q on NM_052851.3) | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs199525321; called by muse, mutect2, varscan2
- TNRC18 | c.4574G>A p.G1525D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1281186653; called by muse, mutect2, varscan2
- TRDMT1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs763830612; called by muse, mutect2, varscan2
- TRIM55 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1563381543; called by muse, varscan2
- UBE2E3 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66585437; called by muse, mutect2, varscan2
- UNC80 | c.8992C>T p.R2998* | Nonsense Mutation (SNP) | VAF 37/138 reads (27%) | catalogued as COSV99778272; called by muse, mutect2, varscan2
- USP13 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 33/224 reads (15%) | catalogued as COSV55863177; called by muse, mutect2, varscan2
- WDFY4 | c.6908G>C p.R2303P | Missense Mutation (SNP) | VAF 85/214 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99631508; called by muse, mutect2, varscan2
- ZBTB21 | c.2299G>T p.E767* | Nonsense Mutation (SNP) | VAF 104/253 reads (41%) | catalogued as COSV60403970; called by muse, mutect2, varscan2
- ZFHX4 | c.8620C>A p.H2874N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99262528; called by muse, mutect2, varscan2
- ZNF491 | c.398G>T p.C133F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs375847840; called by muse, mutect2, varscan2
- ZNF507 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1372457214; called by muse, mutect2, varscan2
- ABCC8 | c.4222G>T p.D1408Y | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.2793G>T p.K931N | Missense Mutation (SNP) | VAF 96/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ADAMTS20 | c.1679dup p.P561Tfs*24 | Frame Shift Ins (INS) | VAF 78/393 reads (20%) | called by mutect2, pindel, varscan2
- ADD2 | c.1113G>T p.M371I | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- ADGRL3 | c.3634A>G p.S1212G (on ENST00000506720 / NM_001322402.2; = p.S1144G on NM_015236.6) | Missense Mutation (SNP) | VAF 184/410 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- AGAP5 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 158/968 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- AK9 | c.1848G>T p.M616I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.013); called by muse, mutect2
- ALB | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 128/339 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ALPK3 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AMPH | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ANKRD26 | c.2130G>T p.L710F | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ANKRD30A | c.3267G>T p.Q1089H (on ENST00000611781; = p.Q1033H on NM_052997.2) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANKRD30B | c.1031A>T p.K344I | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- ANKRD30B | c.2927A>G p.Q976R | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGEF3 | c.4786G>A p.G1596S | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP1A3 | c.223C>A p.L75M (on ENST00000545399 / NM_001256214.2; = p.L62M on NM_152296.5) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- B4GALT6 | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by mutect2, varscan2
- BCL11B | c.2201A>T p.Q734L (on ENST00000357195 / NM_001282237.2; = p.Q663L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BGN | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRINP3 | c.269C>A p.A90E | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTBD1 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- C7orf61 | c.179T>A p.V60D | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- CACNA1E | c.4867A>T p.I1623F | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1H | c.4277_4279delinsAA p.S1426* | Nonsense Mutation (DEL) | VAF 12/57 reads (21%) | called by pindel, varscan2*
- CALR | c.703-2A>T p.X235_splice | Splice Site (SNP) | VAF 126/427 reads (30%) | called by muse, mutect2, varscan2
- CASD1 | c.1906dup p.S636Ffs*24 | Frame Shift Ins (INS) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- CBY2 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCDC186 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 73/188 reads (39%) | called by muse, mutect2, varscan2
- CD19 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CD1C | c.794A>T p.Q265L | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- CDH11 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 51/212 reads (24%) | called by muse, mutect2, varscan2
- CDH23 | c.6906G>T p.M2302I | Missense Mutation (SNP) | VAF 62/433 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by mutect2, varscan2
- CDX4 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.133); called by muse, mutect2
- CECR2 | c.1735G>A p.D579N (on ENST00000342247 / NM_001290047.2; = p.D396N on NM_001290046.1) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CEP192 | c.4730A>C p.H1577P | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CHD6 | c.5628A>T p.E1876D | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CKAP5 | c.3687+1G>T p.X1229_splice | Splice Site (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- CNDP2 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CNKSR2 | c.1465A>T p.K489* | Nonsense Mutation (SNP) | VAF 73/135 reads (54%) | called by muse, mutect2, varscan2
- COL22A1 | c.4070G>T p.G1357V | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.3717+1G>T p.X1239_splice | Splice Site (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- COL22A1 | c.1135C>A p.H379N | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- COL4A6 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.9158C>A p.T3053N (on ENST00000297405 / NM_001363185.1; = p.T2884N on NM_052900.3) | Missense Mutation (SNP) | VAF 139/534 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CSMD3 | c.4622G>A p.G1541E (on ENST00000297405 / NM_001363185.1; = p.G1437E on NM_052900.3) | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CUL3 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DDX28 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DLK1 | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- DLK1 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- DNAH2 | c.4720-2A>G p.X1574_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- DNAH5 | c.12479G>T p.G4160V | Missense Mutation (SNP) | VAF 117/540 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK3 | c.4166G>C p.R1389T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DPP6 | c.359-1G>T p.X120_splice (on ENST00000377770 / NM_001364500.2; = p.X58_splice on NM_001936.5) | Splice Site (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- DSE | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYDC2 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- DYNC1LI1 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.12415C>A p.Q4139K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ECPAS | c.4728G>A p.W1576* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- EDA | c.73T>A p.C25S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- EDC4 | c.2035G>A p.G679S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEA1 | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EIF4G1 | c.2185A>T p.K729* (on ENST00000346169 / NM_198241.3; = p.K534* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 41/363 reads (11%) | called by muse, mutect2, varscan2
- EMB | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EML5 | c.5514G>T p.Q1838H (on ENST00000380664; = p.Q1846H on NM_183387.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- EPB41L3 | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EPHA7 | c.1112G>C p.R371P | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FAM111A | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM187B | c.72C>A p.C24* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- FGF10 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 169/741 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FILIP1L | c.1658T>A p.V553E (on ENST00000354552 / NM_182909.3; = p.V313E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GEN1 | c.2433del p.A813Lfs*8 | Frame Shift Del (DEL) | VAF 34/323 reads (11%) | called by mutect2, pindel, varscan2
- GPC5 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GSAP | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GSAP | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GSDMD | c.1323G>C p.L441F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC9 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HECTD1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- HIVEP2 | c.3770T>C p.L1257S | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- HOXA4 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR5A | c.498G>T p.W166C | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF1R | c.2908G>C p.G970R | Missense Mutation (SNP) | VAF 106/336 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- IGHV1-58 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 75/356 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGHV3-20 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IL6 | c.635T>A p.M212K | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ILDR2 | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- INO80D | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB1 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITIH5 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG1 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 149/466 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JRK | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KANK4 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KAT6A | c.2894G>A p.G965E | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, varscan2
- KCNC2 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- KCNK12 | c.1209C>A p.N403K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KIF2B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.434); called by muse, varscan2
- KIF6 | c.2267G>T p.C756F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KIR2DL4 | c.631C>T p.P211S (on ENST00000396284; = p.P172S on NM_001080770.2) | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KIT | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 240/499 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- KRT77 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KRTAP24-1 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LAMA2 | c.2261G>T p.C754F | Missense Mutation (SNP) | VAF 62/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LHX3 | c.590A>G p.D197G (on ENST00000371748 / NM_178138.6; = p.D202G on NM_014564.5) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LILRA1 | c.569G>A p.S190N | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRRIQ1 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LY6L | c.288_289del p.V97Dfs*94 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- MCM3AP | c.2633del p.R878Pfs*14 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- MEA1 | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MORC1 | c.228A>T p.E76D | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- MTMR12 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- MTUS1 | c.2677G>T p.A893S (on ENST00000262102 / NM_001363061.1; = p.A59S on NM_020749.4) | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC12 | c.12733G>A p.E4245K (on ENST00000379442; = p.E4102K on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT deleterious (0.02); called by muse, mutect2
- MUC16 | c.41050T>A p.Y13684N | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MUC16 | c.7595T>A p.L2532Q | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- MUC22 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MUC3A | c.9219G>T p.E3073D | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- MYH13 | c.2468G>C p.R823P | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MYH2 | c.4188-2A>T p.X1396_splice | Splice Site (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- MYH3 | c.2288A>T p.K763M | Missense Mutation (SNP) | VAF 122/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MYH6 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO7B | c.2020C>A p.Q674K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1L | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- NAV3 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAN | c.1792_1793insA p.A598Dfs*59 | Frame Shift Ins (INS) | VAF 18/91 reads (20%) | called by mutect2, pindel*, varscan2
- NEFM | c.2290G>T p.E764* | Nonsense Mutation (SNP) | VAF 63/214 reads (29%) | called by muse, mutect2, varscan2
- NEO1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 107/384 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NOTCH2 | c.5878G>T p.V1960L | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- NRXN2 | c.4421G>A p.G1474E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NTRK1 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODR4 | c.*2del | Frame Shift Del (DEL) | VAF 57/408 reads (14%) | called by mutect2, pindel, varscan2
- ONECUT2 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OPLAH | c.1393A>G p.M465V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2T12 | c.736G>T p.V246L | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR2T4 | c.299T>A p.L100H | Missense Mutation (SNP) | VAF 99/506 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- OR2T8 | c.876C>G p.N292K | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- OR4C46 | c.683T>G p.L228W | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR4K14 | c.754T>G p.F252V | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR52B4 | c.30C>G p.S10R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OR8U1 | c.215G>C p.C72S | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); called by muse, varscan2
- OTOGL | c.5857C>A p.Q1953K (on ENST00000547103; = p.Q1944K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OTOP2 | c.552G>A p.W184* | Nonsense Mutation (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1978G>T p.D660Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PCDHGA4 | c.2250G>A p.W750* | Nonsense Mutation (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- PCNT | c.9469T>G p.L3157V | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDCD1 | c.456del p.T153Qfs*32 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- PDZD8 | c.2326A>T p.M776L | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDZD8 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PHOX2A | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PKHD1 | c.852del p.F284Lfs*35 | Frame Shift Del (DEL) | VAF 40/348 reads (11%) | called by mutect2, pindel, varscan2
- PLCH1 | c.3117A>T p.Q1039H (on ENST00000340059 / NM_001130960.2; = p.Q1031H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHA6 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PLEKHG7 | c.1812T>A p.D604E | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- POLE | c.6491G>T p.C2164F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- POTEC | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP1R12C | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTGES3 | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- PTPN21 | c.675+1G>T p.X225_splice | Splice Site (SNP) | VAF 43/191 reads (23%) | called by muse, mutect2, varscan2
- PTX3 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- R3HCC1L | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- RAB40A | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); called by muse, mutect2
- RAD51AP1 | c.766G>T p.A256S (on ENST00000228843 / NM_001130862.2; = p.A239S on NM_006479.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RASAL2 | c.2605del p.Q869Rfs*10 | Frame Shift Del (DEL) | VAF 71/198 reads (36%) | called by mutect2, pindel, varscan2
- RASGEF1B | c.1193A>G p.N398S | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM17 | c.856+1G>T p.X286_splice | Splice Site (SNP) | VAF 55/323 reads (17%) | called by muse, mutect2, varscan2
- RCHY1 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REN | c.819-2A>G p.X273_splice | Splice Site (SNP) | VAF 44/227 reads (19%) | called by muse, varscan2
- RFT1 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGL3 | c.176T>G p.L59R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); called by muse, varscan2
- RGS20 | c.708C>G p.H236Q (on ENST00000297313 / NM_170587.4; = p.H89Q on NM_003702.4) | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RIN2 | c.1019C>T p.P340L (on ENST00000255006 / NM_001242581.1; = p.P291L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- RNASE9 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ROBO2 | c.107A>T p.H36L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ROBO2 | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RORB | c.1153T>A p.W385R (on ENST00000396204 / NM_001365023.1; = p.W374R on NM_006914.4) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); called by muse, varscan2
- ROS1 | c.6698C>G p.A2233G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RTTN | c.3523A>T p.R1175* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- SACS | c.45dup p.G16Rfs*45 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | called by pindel, varscan2
- SASH3 | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCN3A | c.2440A>T p.M814L | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- SCN7A | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SCYL2 | c.207dup p.L70Tfs*3 | Frame Shift Ins (INS) | VAF 17/113 reads (15%) | called by mutect2, pindel
- SEMA3E | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 187/657 reads (28%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SETBP1 | c.4775G>T p.S1592I | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- SGIP1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SIRT4 | c.374A>C p.H125P | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A1 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SLC5A5 | c.1796A>G p.K599R | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC6A2 | c.1756G>T p.E586* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- SMAD5 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SOBP | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP8 | c.296C>A p.S99Y (on ENST00000361443 / NM_198956.4; = p.S117Y on NM_182700.6) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, varscan2
- SPAG6 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2
- SPATA31D1 | c.2270del p.H757Pfs*41 | Frame Shift Del (DEL) | VAF 93/420 reads (22%) | called by mutect2, pindel, varscan2
- SRD5A3 | c.878T>C p.F293S | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.079); called by muse, mutect2
- SYNE1 | c.22897C>T p.L7633F (on ENST00000367255 / NM_182961.4; = p.L7562F on NM_033071.3) | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.10553A>G p.Y3518C (on ENST00000367255 / NM_182961.4; = p.Y3525C on NM_033071.3) | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- SYTL5 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- TAF1L | c.1886T>A p.I629N | Missense Mutation (SNP) | VAF 166/258 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- TBC1D20 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCEA2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- TENT4A | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TEP1 | c.3033G>T p.Q1011H | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMC5 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TMEM108 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM132E | c.751A>T p.T251S (on ENST00000321639; = p.T341S on NM_001304438.2) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TMEM191C | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TMEM200A | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNS2 | c.218C>T p.A73V (on ENST00000314250 / NM_170754.4; = p.A83V on NM_015319.2) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TRAF3IP3 | c.494-2A>G p.X165_splice | Splice Site (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- TRAPPC9 | c.3305G>T p.C1102F | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRBV30 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRHDE | c.1911C>A p.Y637* | Nonsense Mutation (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- TRIM49C | c.1178C>A p.T393N | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC3 | c.6045G>T p.Q2015H | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.88049del p.A29350Efs*21 (on ENST00000591111; = p.A21926Efs*21 on NM_003319.4) | Frame Shift Del (DEL) | VAF 74/369 reads (20%) | called by mutect2, pindel, varscan2
- UBTFL1 | c.947C>A p.P316Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by mutect2, varscan2
- UNC13C | c.5249T>A p.L1750Q | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- USH2A | c.6530T>A p.V2177E | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- UTRN | c.8680A>T p.K2894* | Nonsense Mutation (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- WDFY4 | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- XIRP2 | c.3629G>T p.S1210I (on ENST00000628543; = p.S1385I on NM_152381.6) | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ZBED9 | c.3800T>C p.L1267S | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB7A | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZDBF2 | c.5296A>C p.T1766P | Missense Mutation (SNP) | VAF 116/241 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ZIC1 | c.554G>C p.R185P | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZKSCAN1 | c.987T>A p.D329E | Missense Mutation (SNP) | VAF 65/376 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZKSCAN3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- ZNF418 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF439 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2
- ZNF729 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF80 | c.705T>G p.H235Q | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN5B | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ZSCAN5B | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACTN4 | c.267G>A p.E89= | Silent (SNP) | VAF 101/343 reads (29%) | called by muse, mutect2, varscan2
- ADAM22 | c.1083G>C p.G361= | Silent (SNP) | VAF 59/190 reads (31%) | catalogued as COSV99718076; called by muse, mutect2, varscan2
- ANKMY1 | c.2553C>T p.P851= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56040777; called by muse, mutect2, varscan2
- ASTN1 | c.531C>A p.R177= | Silent (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2
- ATP1A3 | c.1923C>T p.N641= (on ENST00000545399 / NM_001256214.2; = p.N628= on NM_152296.5) | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs144130986; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP9B | c.852G>T p.T284= | Silent (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3255T>A p.G1085= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- BIRC2 | c.361C>T p.L121= | Silent (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2
- BNC2 | c.1056G>T p.L352= | Silent (SNP) | VAF 291/471 reads (62%) | catalogued as COSV66141470; called by muse, mutect2, varscan2
- C10orf71 | c.3876C>G p.L1292= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- CABP5 | c.519C>T p.R173= | Silent (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- CALCR | c.1020G>T p.V340= (on ENST00000649521 / NM_001164737.2; = p.V324= on NM_001742.4) | Silent (SNP) | VAF 75/308 reads (24%) | called by muse, mutect2, varscan2
- CASS4 | c.807C>T p.P269= | Silent (SNP) | VAF 37/149 reads (25%) | called by muse, mutect2, varscan2
- CCDC136 | c.2235G>A p.G745= | Silent (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- CCDC39 | c.2082T>C p.A694= | Silent (SNP) | VAF 56/222 reads (25%) | called by muse, mutect2, varscan2
- CDH13 | c.955C>A p.R319= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV51830635; called by muse, mutect2, varscan2
- CLCN1 | c.2526A>T p.S842= | Silent (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.2445G>T p.A815= | Silent (SNP) | VAF 65/291 reads (22%) | catalogued as COSV56697688; called by muse, mutect2, varscan2
- CNTNAP5 | c.2796C>G p.S932= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as COSV70499196; called by muse, mutect2, varscan2
- CYB5R3 | c.9C>T p.A3= | Silent (SNP) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- DACH1 | c.231C>T p.G77= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1435535643; called by muse, mutect2
- DCC | c.507A>T p.P169= | Silent (SNP) | VAF 117/554 reads (21%) | called by muse, mutect2, varscan2
- DCLK2 | c.180G>T p.R60= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99652663; called by muse, mutect2, varscan2
- DYRK2 | c.156G>T p.L52= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ESRRG | c.1050G>T p.L350= | Silent (SNP) | VAF 118/667 reads (18%) | called by muse, mutect2, varscan2
- FBXL7 | c.1071C>T p.I357= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as COSV61646129; called by muse, mutect2, varscan2
- GEMIN4 | c.1029C>T p.Y343= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as rs758088253, COSV56745833; called by muse, mutect2, varscan2
- GLRX3 | c.36C>G p.A12= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- GPR33 | c.912G>A p.E304= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- GRIK1 | c.2097G>A p.A699= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as rs568601127; ClinVar: likely benign; called by muse, mutect2, varscan2
- H3-3B | c.93C>G p.P31= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs746293947; called by muse, mutect2, varscan2
- HAGH | c.804C>G p.T268= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- HOXA1 | c.231G>A p.P77= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as rs575212090; called by muse, mutect2
- IL1RAP | c.513C>G p.V171= | Silent (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- IRX1 | c.918G>T p.L306= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1490893092; called by muse, mutect2, varscan2
- ISLR | c.945C>A p.P315= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- ITGA2B | c.216G>C p.R72= | Silent (SNP) | VAF 69/215 reads (32%) | called by muse, mutect2, varscan2
- KCNIP1 | c.78C>A p.T26= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV66181133; called by muse, mutect2, varscan2
- KMT2B | c.519C>A p.P173= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs375244657; called by muse, mutect2, varscan2
- KRTAP10-9 | c.657C>T p.C219= | Silent (SNP) | VAF 55/302 reads (18%) | called by muse, mutect2, varscan2
- LRP2 | c.11169G>C p.G3723= | Silent (SNP) | VAF 85/455 reads (19%) | called by muse, mutect2, varscan2
- MAGEA3 | c.453C>T p.F151= | Silent (SNP) | VAF 106/195 reads (54%) | called by muse, mutect2, varscan2
- MEFV | c.1251G>T p.L417= | Silent (SNP) | VAF 37/127 reads (29%) | called by muse, mutect2, varscan2
- MMP21 | c.576C>A p.A192= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- MTUS1 | c.1821C>G p.A607= | Silent (SNP) | VAF 60/187 reads (32%) | catalogued as rs375815032, COSV50550554, COSV50554803; called by muse, mutect2, varscan2
- MYT1L | c.420G>A p.E140= | Silent (SNP) | VAF 42/146 reads (29%) | called by muse, mutect2
- NCAN | c.2922G>A p.L974= | Silent (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- NEUROD6 | c.888C>T p.P296= | Silent (SNP) | VAF 112/455 reads (25%) | catalogued as rs1299732505; called by muse, mutect2, varscan2
- OR4N5 | c.333G>A p.E111= | Silent (SNP) | VAF 54/346 reads (16%) | catalogued as COSV61320679; called by muse, mutect2, varscan2
- OR4X2 | c.591C>A p.T197= | Silent (SNP) | VAF 64/269 reads (24%) | catalogued as rs757755618; called by muse, mutect2, varscan2
- OR56A4 | c.510C>T p.F170= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs772468126, COSV58109980; called by muse, mutect2, varscan2
- OR8G1 | c.405C>A p.I135= | Silent (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- OTOG | c.5355C>T p.A1785= | Silent (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- OVGP1 | c.1053G>T p.G351= | Silent (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- PCDH15 | c.2601A>T p.L867= | Silent (SNP) | VAF 78/381 reads (20%) | catalogued as COSV57352737; called by muse, mutect2, varscan2
- PCNT | c.2559G>T p.A853= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs757405970; called by muse, mutect2, varscan2
- PDE5A | c.528C>T p.I176= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as COSV53347972; called by muse, mutect2, varscan2
- PGBD4 | c.1503G>C p.G501= | Silent (SNP) | VAF 78/186 reads (42%) | called by muse, mutect2, varscan2
- PIDD1 | c.2403G>A p.L801= | Silent (SNP) | VAF 30/75 reads (40%) | called by muse, mutect2, varscan2
- PLAA | c.2016A>G p.G672= | Silent (SNP) | VAF 81/141 reads (57%) | called by muse, mutect2, varscan2
- POTEH | c.462G>T p.V154= | Silent (SNP) | VAF 106/658 reads (16%) | called by muse, varscan2
- PREX1 | c.4263G>T p.V1421= | Silent (SNP) | VAF 18/78 reads (23%) | called by muse, mutect2, varscan2
- PTPRR | c.162G>T p.L54= | Silent (SNP) | VAF 137/561 reads (24%) | catalogued as rs138385862; called by muse, mutect2, varscan2
- RELN | c.6594T>C p.S2198= | Silent (SNP) | VAF 53/245 reads (22%) | called by muse, mutect2, varscan2
- RFPL4B | c.777G>T p.L259= | Silent (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- RIPOR2 | c.2709G>T p.L903= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- RNF2 | c.267C>G p.T89= | Silent (SNP) | VAF 115/285 reads (40%) | catalogued as rs1446611619; called by muse, mutect2, varscan2
- RPH3A | c.165A>G p.K55= (on ENST00000389385 / NM_001143854.2; = p.K51= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- RREB1 | c.3528G>T p.G1176= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV58558716; called by muse, mutect2, varscan2
- RSPH4A | c.1468C>A p.R490= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as CM090750, COSV57633727; called by muse, varscan2
- S1PR1 | c.627C>A p.V209= | Silent (SNP) | VAF 58/147 reads (39%) | called by muse, mutect2, varscan2
- SCN10A | c.2844G>T p.V948= | Silent (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- SERPINA9 | c.651C>T p.H217= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs1400529842, COSV54075277; called by muse, mutect2, varscan2
- SETD2 | c.2004C>T p.P668= | Silent (SNP) | VAF 41/115 reads (36%) | catalogued as rs778126699; called by muse, mutect2, varscan2
- SEZ6 | c.157C>A p.R53= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100253017; called by muse, mutect2, varscan2
- SHANK1 | c.3663C>T p.S1221= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99521253; called by muse, mutect2
- SIGLEC5 | c.276C>A p.L92= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV99707440; called by muse, mutect2, varscan2
- SLC12A7 | c.999A>T p.S333= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- SLC13A1 | c.996G>T p.V332= | Silent (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- SLC18A3 | c.39G>T p.A13= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1686T>C p.S562= | Silent (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- SLITRK5 | c.1662A>T p.S554= | Silent (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- SPATA48 | c.1293G>A p.K431= | Silent (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
- SPTA1 | c.4323A>G p.K1441= | Silent (SNP) | VAF 148/449 reads (33%) | catalogued as COSV63752765; called by muse, mutect2, varscan2
- TEKT3 | c.189A>C p.P63= | Silent (SNP) | VAF 57/203 reads (28%) | called by muse, mutect2, varscan2
- TNN | c.1305C>A p.I435= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV99511954; called by muse, mutect2, varscan2
- TOGARAM1 | c.2361C>T p.G787= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- TP53INP2 | c.336C>A p.G112= | Silent (SNP) | VAF 60/183 reads (33%) | called by muse, mutect2, varscan2
- TRPM5 | c.78C>T p.G26= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as rs759599505, COSV99329902; called by muse, mutect2, varscan2
- TSPO2 | c.36C>A p.P12= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.9630C>A p.T3210= (on ENST00000591111; = p.T3164= on NM_003319.4) | Silent (SNP) | VAF 83/360 reads (23%) | called by muse, mutect2, varscan2
- UNC79 | c.3105G>C p.L1035= (on ENST00000393151 / NM_001346218.2; = p.L858= on NM_020818.5) | Silent (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- XCR1 | c.177T>C p.Y59= | Silent (SNP) | VAF 54/140 reads (39%) | called by muse, mutect2, varscan2
- ZFHX4 | c.2607G>T p.P869= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs763801174; called by muse, mutect2, varscan2
- ZNF281 | c.1971T>G p.P657= | Silent (SNP) | VAF 59/253 reads (23%) | called by muse, mutect2, varscan2
- AARS2 | c.2794-21C>G | Intron (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- AC002059.3 | chr22:29419247 C>G | 3'Flank (SNP) | VAF 56/287 reads (20%) | called by muse, varscan2
- AC068587.7 | chr8:12659409 G>T | 5'Flank (SNP) | VAF 22/42 reads (52%) | catalogued as rs1407765378; called by muse, mutect2, varscan2
- ADGRE4P | n.106C>T | RNA (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- ANKRD30BL | c.614+1079T>C | Intron (SNP) | VAF 45/253 reads (18%) | called by muse, mutect2, varscan2
- ATPAF1 | chr1:46633766 C>G | 3'Flank (SNP) | VAF 62/442 reads (14%) | called by muse, varscan2
- BDKRB2 | c.74+607A>C | Intron (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- C6orf223 | n.613C>A | RNA (SNP) | VAF 27/212 reads (13%) | called by muse, mutect2, varscan2
- CCDC74A | c.295+354G>T | Intron (SNP) | VAF 25/94 reads (27%) | called by muse, mutect2, varscan2
- CCSER1 | c.2217+233695T>C | Intron (SNP) | VAF 53/181 reads (29%) | called by muse, mutect2, varscan2
- CHODL | c.*29G>T | 3'UTR (SNP) | VAF 97/330 reads (29%) | catalogued as rs576531181; called by muse, mutect2, varscan2
- CMAHP | n.1258A>T | RNA (SNP) | VAF 61/416 reads (15%) | called by muse, mutect2, varscan2
- CNTN4 | c.56-247G>A | Intron (SNP) | VAF 70/320 reads (22%) | catalogued as rs181130113; called by muse, mutect2, varscan2
- CPED1 | c.2311-4583G>A | Intron (SNP) | VAF 71/260 reads (27%) | called by muse, mutect2, varscan2
- DAPK3 | c.630-333G>A | Intron (SNP) | VAF 27/109 reads (25%) | catalogued as rs768877722; called by muse, mutect2, varscan2
- DCAF17 | c.*3361A>T | 3'UTR (SNP) | VAF 19/71 reads (27%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53009422 ins A | 5'Flank (INS) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- FAM167A | c.381+5865G>A | Intron (SNP) | VAF 19/60 reads (32%) | catalogued as rs1007414585, COSV99453439; called by muse, mutect2, varscan2
- GPATCH1 | c.-5G>A | 5'UTR (SNP) | VAF 49/175 reads (28%) | catalogued as rs1322594056; called by muse, mutect2, varscan2
- GRIA4 | c.487+44603C>T | Intron (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- LILRB1 | chr19:54638745 C>A | 3'Flank (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- LINC00905 | n.547C>A | RNA (SNP) | VAF 49/140 reads (35%) | called by mutect2, varscan2
- LRRIQ3 | c.707+11241G>A | Intron (SNP) | VAF 34/102 reads (33%) | catalogued as rs978063621; called by muse, mutect2, varscan2
- MAN1A2 | c.*257G>T | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1128T>C | Intron (SNP) | VAF 81/359 reads (23%) | called by muse, mutect2, varscan2
- MIA3 | c.5414-356T>C | Intron (SNP) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MOCS1 | c.645+14C>T | Intron (SNP) | VAF 77/248 reads (31%) | called by muse, mutect2, varscan2
- MRC1 | c.-61G>A | 5'UTR (SNP) | VAF 61/252 reads (24%) | called by muse, mutect2, varscan2
- MYH14 | c.*56G>T | 3'UTR (SNP) | VAF 10/43 reads (23%) | catalogued as rs780715963; called by muse, mutect2, varscan2
- NCAPH | c.-16G>T | 5'UTR (SNP) | VAF 72/124 reads (58%) | called by muse, mutect2, varscan2
- NEB | c.18826-2980A>T | Intron (SNP) | VAF 42/223 reads (19%) | catalogued as rs1245754241; called by muse, mutect2, varscan2
- OR4F13P | n.897G>T | RNA (SNP) | VAF 75/203 reads (37%) | called by muse, mutect2, varscan2
- OSBPL2 | chr20:62233321 G>T | 5'Flank (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1994G>A | RNA (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157243 C>T | 3'Flank (SNP) | VAF 143/387 reads (37%) | catalogued as rs782640379; called by muse, mutect2, varscan2
- PEX16 | c.*135G>C | 3'UTR (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- PHKA2 | c.3283-10C>T | Intron (SNP) | VAF 105/192 reads (55%) | called by muse, mutect2, varscan2
- PROS1 | c.*18T>A | 3'UTR (SNP) | VAF 37/216 reads (17%) | called by muse, mutect2, varscan2
- PSMG4 | c.250+555C>T | Intron (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- RFK | chr9:76398706 G>T | 5'Flank (SNP) | VAF 22/145 reads (15%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+1280C>G | Intron (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- SERPING1 | c.685+12G>A | Intron (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- SLC46A3 | c.*540G>A | 3'UTR (SNP) | VAF 21/116 reads (18%) | catalogued as COSV57180261; called by muse, mutect2, varscan2
- SLC8A1 | c.1915+629A>T | Intron (SNP) | VAF 68/184 reads (37%) | called by muse, mutect2, varscan2
- SPRING1 | c.*3G>C | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- STX10 | c.-28G>T | 5'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- SUPT3H | c.135-91693T>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2232T>A | 3'UTR (SNP) | VAF 77/198 reads (39%) | called by muse, mutect2, varscan2
- TNRC18 | chr7:5428034 G>C | 5'Flank (SNP) | VAF 10/102 reads (10%) | called by mutect2, varscan2
- TOMM34 | c.127+1832G>C | Intron (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- TSPO2 | c.-21+26C>T | Intron (SNP) | VAF 57/206 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.34264+3344C>A | Intron (SNP) | VAF 32/156 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10361-3673C>T | Intron (SNP) | VAF 29/173 reads (17%) | called by muse, mutect2, varscan2
- UBTFL2 | n.956C>A | RNA (SNP) | VAF 12/98 reads (12%) | called by mutect2, varscan2
- UNKL | chr16:1414742 C>A | 5'Flank (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- UQCRB | c.*3014G>T | 3'UTR (SNP) | VAF 118/322 reads (37%) | called by muse, varscan2
- XIRP2 | c.-22C>A | 5'UTR (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+43943C>G | Intron (SNP) | VAF 56/228 reads (25%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-533+67C>T | Intron (SNP) | VAF 37/163 reads (23%) | catalogued as COSV73947906; called by muse, mutect2, varscan2
- ZFHX4 | c.3325+3779G>T | Intron (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- ZNF252P | n.876G>T | RNA (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- ZNF833P | n.774T>A | RNA (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- ZNF849P | n.50G>A | RNA (SNP) | VAF 9/35 reads (26%) | catalogued as rs556494383; called by muse, mutect2, varscan2
- ZNF99 | c.*3277C>G | 3'UTR (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
